Somatic mutation profile of tumor specimen TCGA-A6-5656-01A (aliquot TCGA-A6-5656-01A-21D-1835-10) from TCGA case TCGA-A6-5656, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 74.4 years (27,184 days).
Specimen TCGA-A6-5656-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d4e0426-fa48-4025-a1cc-e92483247a0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-5656-10A (Blood Derived Normal), aliquot TCGA-A6-5656-10A-01D-A270-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/731548e6-29cf-4596-b833-b09dac6304af

The open-access MAF lists 108 somatic variants for this specimen: 80 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 26, Nonsense Mutation 4, In Frame Del 2, Splice Region 2, Intron 1, Frame Shift Del 1, 3'UTR 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.2624C>T p.T875M (on ENST00000303395 / NM_001202435.3; = p.T864M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs121918623, CM000569, CM096132, COSV57669847; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 11/16 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1336401643, COSV60916667; called by muse, mutect2, varscan2
- ADAM32 | c.1080C>A p.S360R | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101165455, COSV65952405; called by muse, mutect2, varscan2
- AFAP1L1 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs371511486; called by muse, mutect2, varscan2
- ANKRD30A | c.691G>A p.V231I (on ENST00000611781; = p.V175I on NM_052997.2) | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.039); catalogued as rs200565471, COSV64616844; called by muse, mutect2, varscan2
- APC | c.4314del p.P1439Lfs*34 | Frame Shift Del (DEL) | VAF 25/65 reads (38%) | catalogued as COSV57354045, COSV57378825; called by mutect2, pindel, varscan2
- ARHGAP31 | c.1508G>A p.S503N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.432); catalogued as COSV99957482; called by muse, mutect2, varscan2
- ATAD2B | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99478178; called by muse, mutect2, varscan2
- ATP12A | c.2735A>C p.D912A | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV99518147; called by muse, mutect2, varscan2
- B3GALT2 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs769360180, COSV66464407; called by muse, mutect2, varscan2
- CABS1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs758926757, COSV56733074; called by muse, mutect2, varscan2
- CENPF | c.6599T>C p.V2200A | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV65277509; called by muse, mutect2, varscan2
- CHAT | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs751583653, COSV60324985, COSV60328624; called by muse, varscan2
- CHST15 | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs774519865, COSV60565153; called by muse, mutect2, varscan2
- CNTROB | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV58050786; called by muse, mutect2, varscan2
- COL5A3 | c.4291C>T p.P1431S | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370896010; called by muse, mutect2, varscan2
- CRB1 | c.701T>C p.L234S | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV100959171; called by muse, mutect2, varscan2
- DBF4B | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as rs139442134; called by muse, mutect2, varscan2
- DCDC1 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as rs369097377, COSV60833095; called by muse, mutect2, varscan2
- DCX | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 74/84 reads (88%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as rs1305044719, COSV57573151; called by muse, mutect2, varscan2
- DST | c.4474C>T p.L1492F (on ENST00000361203 / NM_001374722.1; = p.L1166F on NM_015548.5) | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55031198; called by muse, mutect2, varscan2
- F10 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV65021670; called by muse, mutect2, varscan2
- F8 | c.3870dup p.G1291Rfs*29 | Frame Shift Ins (INS) | VAF 48/108 reads (44%) | catalogued as rs1426645898; called by mutect2, varscan2
- FAM83C | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs748263316, COSV65583935; called by muse, mutect2, varscan2
- GALNT6 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as rs769886850, COSV62542698; called by muse, mutect2, varscan2
- GAPDHS | c.66G>A p.P22= | Splice Region (SNP) | VAF 7/17 reads (41%) | catalogued as rs925809724, COSV99722860; called by muse, mutect2, varscan2
- GIPC3 | c.591C>T p.F197= | Splice Region (SNP) | VAF 7/14 reads (50%) | catalogued as rs759536524, COSV59260296; called by muse, mutect2, varscan2
- GRID1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs771100097, COSV60044117; called by muse, mutect2, varscan2
- HAVCR2 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs147605860; called by muse, mutect2, varscan2
- HECW1 | c.4373C>T p.A1458V | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV67839253; called by muse, mutect2, varscan2
- IARS2 | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759787338, COSV56961947; called by muse, varscan2
- ILDR2 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs201864196, COSV54831468; called by muse, mutect2, varscan2
- ITPR1 | c.2188G>A p.V730I (on ENST00000354582; = p.V715I on NM_002222.7) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as rs370701686; called by muse, mutect2, varscan2
- KLHL30 | c.93G>C p.K31N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59977562; called by muse, mutect2, varscan2
- KRT77 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as rs774353164, COSV59238663; called by muse, mutect2, varscan2
- KRT85 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as rs370478744; called by muse, mutect2, varscan2
- LOXL4 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs921568799, COSV99583869; called by muse, mutect2, varscan2
- LRCH4 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs769364186, COSV59644063; called by muse, mutect2, varscan2
- LRRC14B | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.085); catalogued as rs368280607; called by muse, mutect2, varscan2
- NEDD4L | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.118); catalogued as COSV56849999; called by muse, mutect2, varscan2
- NSD1 | c.6479C>T p.P2160L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327420643, COSV61772420; called by muse, mutect2
- OR5M8 | c.808G>T p.G270C | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59117700; called by muse, mutect2, varscan2
- OR5T2 | c.482G>C p.R161P | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV57589665, COSV57590384; called by muse, mutect2, varscan2
- PCDH15 | c.5015C>A p.S1672Y | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as COSV100225164; called by muse, mutect2, varscan2
- PCDH15 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.519); catalogued as COSV57364103; called by muse, mutect2, varscan2
- PCDHGB4 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as rs748559328, COSV53895525; called by muse, mutect2, varscan2
- PCDHGB4 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.378); catalogued as COSV54001285; called by muse, mutect2, varscan2
- PHACTR3 | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.804); catalogued as COSV100732967; called by muse, mutect2, varscan2
- PI4K2B | c.1109C>G p.A370G | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53512460; called by muse, mutect2, varscan2
- PIK3C2B | c.2057G>A p.W686* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100916187; called by muse, mutect2
- PLEKHA8 | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV51653757; called by muse, mutect2, varscan2
- POU6F2 | c.330G>T p.M110I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV101302791; called by muse, mutect2
- PRSS54 | c.185C>G p.S62C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV99541688; called by muse, varscan2
- RXFP3 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs1225974660, COSV57503985; called by muse, mutect2, varscan2
- RYR1 | c.10520C>T p.T3507M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371839408; called by muse, mutect2, varscan2
- SERPIND1 | c.1189T>A p.F397I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53140133; called by muse, mutect2, varscan2
- SIN3B | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs546578699, COSV99931921; called by muse, mutect2
- SLC15A1 | c.21+1G>A p.X7_splice | Splice Site (SNP) | VAF 67/126 reads (53%) | catalogued as rs374661720; called by muse, mutect2, varscan2
- SLC37A4 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1417623185, COSV58155952; called by muse, mutect2, varscan2
- SP100 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs766779368, COSV50975085; called by muse, mutect2, varscan2
- STAC | c.335A>T p.E112V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99830442; called by muse, mutect2, varscan2
- STOX2 | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs369084419; called by muse, mutect2, varscan2
- TAAR2 | c.47C>A p.T16K | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1177801802, COSV100907965; called by muse, mutect2
- TBCCD1 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs552386653, COSV58661931; called by muse, mutect2, varscan2
- TBX3 | c.821C>G p.P274R (on ENST00000257566 / NM_016569.4; = p.P254R on NM_005996.4) | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57472188, COSV57474198; called by muse, mutect2, varscan2
- TCHP | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 31/91 reads (34%) | catalogued as COSV100452643, COSV57166180; called by muse, mutect2, varscan2
- THEG | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs372037486; called by muse, mutect2, varscan2
- TIMD4 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs773468118, COSV50858004; called by muse, mutect2, varscan2
- TLCD3B | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as rs933771891, COSV54227812; called by muse, mutect2, varscan2
- TMEM163 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.05); catalogued as rs755523021, COSV56110820; called by muse, mutect2, varscan2
- TNS1 | c.3913G>A p.G1305R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as rs202059695, COSV50690570, COSV50697046; called by muse, mutect2, varscan2
- TNXB | c.8779G>A p.G2927R (on ENST00000647633; = p.G2680R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs759066378, COSV64485348; called by muse, mutect2, varscan2
- TSHZ3 | c.2444C>T p.P815L | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs766793830, COSV53669970; called by muse, varscan2
- TTN | c.54926G>A p.R18309Q (on ENST00000591111; = p.R10885Q on NM_003319.4) | Missense Mutation (SNP) | VAF 60/93 reads (65%) | PolyPhen probably damaging (0.947); catalogued as rs374914334; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VSTM2L | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 57/76 reads (75%) | SIFT tolerated (0.27); PolyPhen benign (0.139); catalogued as rs1377938011, COSV65096259; called by muse, mutect2, varscan2
- ZNF227 | c.386G>A p.R129K | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100480540; called by muse, varscan2
- EIF3A | c.384_386del p.L129del | In Frame Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- RELCH | c.2001_2003del p.I667del | In Frame Del (DEL) | VAF 27/38 reads (71%) | called by mutect2, pindel, varscan2
- ROR2 | c.1669T>C p.S557P | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, varscan2
- ADGRD1 | c.90G>A p.S30= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as rs748431281, COSV55442071; called by muse, mutect2, varscan2
- C12orf57 | c.168C>T p.P56= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs143343192, COSV57547346, COSV99980783; called by muse, mutect2, varscan2
- CCDC54 | c.453G>A p.T151= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as rs142151683; called by muse, mutect2, varscan2
- CELSR3 | c.8481C>T p.T2827= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs766138738, COSV99374421; called by mutect2, varscan2
- COL20A1 | c.2853C>T p.A951= | Silent (SNP) | VAF 22/32 reads (69%) | catalogued as rs746587840, COSV58924015; called by muse, mutect2, varscan2
- EMILIN3 | c.1431C>T p.L477= | Silent (SNP) | VAF 51/70 reads (73%) | catalogued as rs140838664; called by muse, mutect2, varscan2
- GCM2 | c.444G>A p.A148= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs542569618, COSV65275559; called by muse, mutect2, varscan2
- KCNK13 | c.744C>T p.N248= | Silent (SNP) | VAF 46/59 reads (78%) | catalogued as rs574638305, COSV56411938; called by muse, mutect2, varscan2
- LCE3E | c.237C>T p.G79= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs540273209, COSV64232081; called by muse, mutect2, varscan2
- MACF1 | c.17790C>T p.D5930= (on ENST00000372915; = p.D3975= on NM_012090.5) | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs766713562, COSV57135287; called by muse, mutect2, varscan2
- NAPRT | c.252G>T p.L84= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99435243; called by muse, mutect2
- OR10J3 | c.972G>A p.A324= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs201786076, COSV100171731; called by muse, mutect2, varscan2
- OR4B1 | c.756T>C p.A252= | Silent (SNP) | VAF 56/80 reads (70%) | catalogued as COSV58883536; called by muse, mutect2, varscan2
- OS9 | c.114G>A p.E38= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV57784149; called by muse, mutect2, varscan2
- PCDHA2 | c.1767C>T p.H589= | Silent (SNP) | VAF 69/164 reads (42%) | catalogued as rs782740005, COSV65369794; called by muse, mutect2, varscan2
- PEX13 | c.561T>A p.T187= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV54371029; called by muse, mutect2, varscan2
- PLXNA4 | c.972G>A p.R324= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV100327896; called by muse, mutect2
- PRF1 | c.363G>A p.A121= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs146358730; called by muse, mutect2, varscan2
- RASGRF1 | c.852C>T p.D284= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs754755775, COSV69181725; called by muse, varscan2
- RRM1 | c.993T>C p.A331= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as rs750572935, COSV100331403; called by muse, mutect2, varscan2
- RUBCN | c.2226G>A p.L742= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as rs1340064026; called by muse, mutect2
- SIM1 | c.1623G>A p.S541= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as rs760045551, COSV53492414; called by muse, mutect2, varscan2
- TPP1 | c.1437A>G p.P479= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100196550; called by muse, mutect2, varscan2
- TPRX1 | c.912G>A p.P304= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as rs775098024, COSV59116827; called by muse, mutect2, varscan2
- ZNF431 | c.609T>C p.P203= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV60674608; called by muse, mutect2, varscan2
- ZNF497 | c.633G>A p.T211= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV54050720; called by muse, mutect2, varscan2
- KDELR2 | c.*117A>G | 3'UTR (SNP) | VAF 84/132 reads (64%) | catalogued as COSV51727386; called by muse, mutect2, varscan2
- PIK3R1 | c.917-1526A>G | Intron (SNP) | VAF 45/123 reads (37%) | catalogued as COSV99148973; called by muse, mutect2, varscan2
